Somatic mutation profile of tumor specimen BA3192D (aliquot aq-BA3192D) from BEATAML1.0 case 2475, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,440 days).
Specimen BA3192D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 572bcf10-3148-4304-bcfe-c1d9675506b3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3198D (Solid Tissue Normal), aliquot aq-BA3198D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89ab3f81-d482-449b-9e75-109828a4802f

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 16/32 reads (50%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KIT | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 15/463 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55399286; called by muse, mutect2
- LTBP1 | c.3418G>T p.G1140C (on ENST00000404816 / NM_206943.4; = p.G814C on NM_000627.4) | Missense Mutation (SNP) | VAF 95/217 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750811131; called by muse, mutect2, varscan2
- ZBTB47 | c.1659C>G p.C553W | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51763844; called by muse, mutect2, varscan2
- IMMP2L | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
